Somatic mutation profile of tumor specimen CPT008918 (aliquot CPT008918-0002) from CPTAC case 01BR026, project CPTAC-2 (Breast). Tissue or organ of origin: Breast, NOS.
Specimen CPT008918: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da90c8e2-5d5f-40e1-b8be-03f7fca6bd43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT008539 (Blood Derived Normal), aliquot CPT008539-0001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bf40784-f189-45c8-b2dc-ca7dcc2bd2a0

The open-access MAF lists 49 somatic variants for this specimen: 29 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 14, Frame Shift Del 3, Frame Shift Ins 2, 5'Flank 2, Intron 2, Nonsense Mutation 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK9 | c.2778G>C p.K926N | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.422); catalogued as COSV100393750; called by muse, mutect2, varscan2
- ALDH18A1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV64662519; called by muse, mutect2
- AMER3 | c.101C>G p.T34R | Missense Mutation (SNP) | VAF 22/291 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs767464409; called by muse, mutect2
- CD72 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.427); catalogued as rs766540486, COSV52410421; called by muse, mutect2
- DMRTA2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1390282150; called by muse, mutect2, varscan2
- LPA | c.3807del p.T1270Qfs*32 | Frame Shift Del (DEL) | VAF 14/136 reads (10%) | catalogued as COSV60295822; called by pindel, varscan2
- NUDT11 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557326680, COSV65665078; called by muse, mutect2
- OR4X1 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 36/414 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs533909225; called by muse, mutect2
- RTL9 | c.2842G>A p.G948R | Missense Mutation (SNP) | VAF 95/400 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.595); catalogued as rs754486365, COSV101511739; called by muse, mutect2, varscan2
- VIPR1 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138002757; called by muse, varscan2
- ARHGAP24 | c.151T>C p.F51L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2
- ARSB | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CCDC102B | c.799T>G p.F267V | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CCDC158 | c.1906A>G p.K636E | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.64); called by muse, mutect2
- CENPF | c.8560dup p.T2854Nfs*6 | Frame Shift Ins (INS) | VAF 14/142 reads (10%) | called by mutect2, pindel
- DHX38 | c.2103C>G p.I701M | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- DNAH11 | c.11847A>C p.R3949S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- GSE1 | c.2718G>C p.L906F | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HMCN1 | c.15232A>G p.K5078E | Missense Mutation (SNP) | VAF 25/360 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2
- MAP6 | c.1981C>G p.Q661E | Missense Mutation (SNP) | VAF 77/459 reads (17%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PKD2 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2
- PPARG | c.852G>A p.M284I (on ENST00000287820 / NM_015869.5; = p.M254I on NM_005037.7) | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2
- PRPF8 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RBM15 | c.990_993del p.R331Tfs*50 | Frame Shift Del (DEL) | VAF 35/256 reads (14%) | called by mutect2, varscan2
- RTKN | c.59dup p.M20Ifs*29 | Frame Shift Ins (INS) | VAF 40/199 reads (20%) | called by mutect2, pindel, varscan2
- TNS2 | c.126_127del p.K42Nfs*8 (on ENST00000314250 / NM_170754.4; = p.K52Nfs*8 on NM_015319.2) | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | called by mutect2, pindel, varscan2
- TOPBP1 | c.2281G>C p.D761H | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- TTN | c.53419A>T p.K17807* (on ENST00000591111; = p.K10383* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2
- ZNF41 | c.796C>G p.P266A | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- ACTL10 | c.171G>A p.R57= | Silent (SNP) | VAF 80/374 reads (21%) | called by mutect2, varscan2
- ADGRA1 | c.726C>T p.G242= | Silent (SNP) | VAF 38/331 reads (11%) | catalogued as rs755111182; called by muse, mutect2, varscan2
- CD1E | c.495C>A p.A165= | Silent (SNP) | VAF 25/232 reads (11%) | called by muse, mutect2, varscan2
- EOLA2 | c.303C>G p.P101= | Silent (SNP) | VAF 57/381 reads (15%) | catalogued as rs368857106, COSV100778083; called by muse, mutect2, varscan2
- GNB1L | c.18G>A p.P6= | Silent (SNP) | VAF 27/289 reads (9%) | catalogued as rs372981804; called by muse, mutect2
- HCN1 | c.1458C>A p.A486= | Silent (SNP) | VAF 58/300 reads (19%) | called by mutect2, varscan2
- KANK1 | c.1083G>A p.T361= | Silent (SNP) | VAF 24/336 reads (7%) | catalogued as rs534950294, COSV63216793; called by muse, mutect2
- LMTK2 | c.3696G>A p.T1232= | Silent (SNP) | VAF 26/340 reads (8%) | catalogued as rs145993561; called by muse, mutect2
- MEGF8 | c.7506C>G p.L2502= (on ENST00000251268 / NM_001271938.2; = p.L2435= on NM_001410.3) | Silent (SNP) | VAF 37/284 reads (13%) | called by muse, mutect2, varscan2
- PCDHGC5 | c.822C>T p.N274= | Silent (SNP) | VAF 46/293 reads (16%) | catalogued as rs758715682; called by muse, mutect2, varscan2
- PLCD4 | c.1137C>T p.V379= | Silent (SNP) | VAF 51/311 reads (16%) | called by muse, mutect2, varscan2
- POLDIP3 | c.750G>A p.L250= | Silent (SNP) | VAF 33/167 reads (20%) | catalogued as COSV52808599; called by muse, mutect2, varscan2
- TMEM132C | c.3195C>T p.D1065= | Silent (SNP) | VAF 19/261 reads (7%) | catalogued as rs376260103; called by muse, mutect2
- TYRO3 | c.888C>T p.L296= | Silent (SNP) | VAF 36/212 reads (17%) | called by muse, mutect2
- CEP41 | chr7:130441194 G>C | 5'Flank (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2
- CNOT9 | c.-16G>C | 5'UTR (SNP) | VAF 14/79 reads (18%) | called by muse, varscan2
- CTRB2 | c.236+44G>C | Intron (SNP) | VAF 59/288 reads (20%) | called by muse, mutect2, varscan2
- DNAH8 | chr6:38723114 C>A | 5'Flank (SNP) | VAF 29/317 reads (9%) | called by muse, mutect2
- EPOR | c.251+71del | Intron (DEL) | VAF 60/313 reads (19%) | called by mutect2, pindel, varscan2
- MAPK8IP1 | c.*42G>T | 3'UTR (SNP) | VAF 56/235 reads (24%) | called by muse, mutect2, varscan2
